CCDI case PBBSRJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/0996c952-9e36-4649-82de-3ccf8f981105

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 10.2 years (3,740 days).

Biospecimens (3 samples)
- Sample 0DFYPH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFYQC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFYQS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
